Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CK, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CK-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

ICD-0-3
Carcinoma, papillary, follicular variant
8340/3
Site: thyroid, NOS C73.9 w/ 6/18/14

Reviewed (Initials)	w/ 6/18/14 6/7/11	

Specimen(s) Received

1. Nck: RIGHT JUGULAR NODE-STITCH MARKS APEX
2. Neck:right posterior triangle - stitch marks apex
3. level 5A lymph nodes right neck
4. left lower parathyroid- QS
5. total thyroidectomy stitch mark upper right pole
6. right lower parathyroid - QS

Diagnosis

1. Metastatic papillary thyroid carcinoma, classical variant, with extranodal extension: Lymph node (right jugular) biopsy
2. Metastatic papillary thyroid carcinoma, classical variant: Lymph nodes, 4/19 (right posterior triangle) dissection
3. No pathological diagnosis: Lymph nodes, 3 (right level 5A) dissection specimen
4. No pathological diagnosis: Parathyroid
No pathological diagnosis: Thymus
- (left lower neck) biopsy
5. Multifocal papillary carcinoma, dominant 2.3 cm, right, follicular variant; second 0.6 cm, right, classical variant: Thyroid
Metastatic papillary thyroid carcinoma: Lymph node, 1 of 2, isthmic
- Total thyroidectomy specimen
6. No pathological diagnosis: Parathyroid (right lower) biopsy

Synoptic Data

Clinical History:	No radiation exposure
Procedure:	Total thyroidectomy with right neck dissection
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe: 4.5 cm 2.8 cm 2.2 cm

[page 2 of 4]
	Left lobe:
	4 cm
	2.5 cm
	1.5 cm
	Isthmus +/- pyramidal lobe:
	4.8 cm
	1.6 cm
	0.8 cm
	Right neck dissection:
	20.2 cm
	7 cm
	3.5 cm
Specimen Weight:	24.5 g
Tumor Focality:	Multifocal, ipsilateral
	Multifocal, midline (isthmus)
----- DOMINANT TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 2.3cm
	Additional dimension: 1.7 cm
	Additional dimension: 1.5 cm
Histologic Type:	Papillary carcinoma, follicular variant
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 0.6cm
	Additional dimensions: 0.4 cm
Histologic Type:	Papillary carcinoma, classical (usual)
	Classical (papillary) architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
	Distance of invasive carcinoma to closest margin: 1mm
Tumor Capsule:	None
Tumor Capsular Invasion:	Present, extent widely invasive
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
	Number of regional lymph nodes examined: 25
	Number of regional lymph nodes involved: 6
	Lymph Node, Extranodal Extension Present
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Parathyroid gland(s), within normal limits
	Other: additional 2 papillary microcarcinomas in the isthmus, 0.1 and 0.3 cm

[page 3 of 4]
Ancillary Studies:

Type: immunohistochemistry

Results: Dominant nodule - CK 19 positive, galectin negative, HBME 1 focally positive; second dominant nodule CK 19 positive, galectin positive, HBME 1 positive; largest metastatic lymph node - CK 19 positive, galectin positive, HBME 1 positive

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Comment

The dominant nodule stains for CK19 and focally for HBME-1 but is negative for galectin-3. In contrast, the second dominant nodule is strongly positive for CK19, galectin-3 and HBME-1, similar to the pattern seen in the metastatic lymph node. This immunoprofile and the morphology indicate that the metastasizing tumor is the second dominant nodule (widely invasive classical variant papillary carcinoma, 0.6 cm, right).

verified by:

Electronically

Gross Description

1. The specimen labeled with the patient's name and as "right jugular node-stitch marks apex" consists of a piece of fibrofatty tissue and muscle oriented with a stitch marking the apex, measuring 5.7 x 2.7 x 1.5 cm received in 10% buffered formalin. One lymph node is identified in the area of the stitch; it measures 1.6 cm in diameter. It is solid to cystic on cut surface. The specimen is submitted as follows:

1A,B lymph node sectioned in toto.

2. The specimen labeled with the patient's name and as "right posterior triangle-stitch marks apex" consists of a piece of fibroadipose tissue that measures 10.5 x 2.3 x 1.5 cm oriented with a stitch marking the apex, received in 10% buffered formalin. Multiple lymph nodes are identified measuring from 0.3 cm to 3.5 cm in diameter. The largest is partly cystic on cut surface. The lymph nodes are submitted in toto from apex to opposite end as follows:

2A,B, multiple lymph nodes, each block

2C-F largest lymph node sectioned

2G multiple lymph nodes

2H two lymph nodes

2I one lymph node bisected

2J,K two lymph nodes each block

3. The specimen labeled with the patient's name and as "level 5A lymph nodes, right neck" consists of one piece of fibroadipose tissue that measures 3.5 x 2 x 1 cm received in 10% buffered formalin. Three lymph nodes measure from 0.2-cm to 2.2 cm in diameter. The specimen is submitted as follows:

3A one lymph node

3B,C one lymph node bisected each block.

4. The specimen labeled with the patient's name and as "left lower parathyroid qs" consists of a tiny piece of tissue that measures less than 0.1 cm in maximum dimension. It is frozen for intraoperative consultation.

4A frozen section block resubmitted.

[page 4 of 4]
5. The specimen labeled with the patient's name and as "total thyroidectomy, stitch marks right upper pole" consists of a thyroid gland that is oriented with a suture and weighs 24.5 g. The right lobe measures 4.5 cm SI x 2.8 cm ML x 2.2 cm AP, the left lobe measures 4.0 cm SI x, 2.5 cm ML x, 1.5 cm AP and the isthmus measures 4.8 cm SI x 1.6 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands and/or lymph nodes are identified grossly. The external surface is painted with Silver nitrate. The right lobe contains two well delineated nodules, one upper and one lower, that measure 0.6 cm SI x 0.4 cm ML x 0.4 cm AP and 2.3 cm SI x 1.7 cm ML x 1.5 cm AP respectively. The lower pole of the left lobe contains a well delineated nodule that measures 0.3 cm SI x 0.4 cm ML x 0.4 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Two sections of right lobe nodule, one section of the left lobe nodule and one piece of normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

5A-L right lobe, superior to inferior

5M-Q isthmus

5R-Z left lobe, superior to inferior

6. The specimen labeled with the patient's name and as "right lower parathyroid qs" consists of a piece of tissue that measures 0.4 cm in maximum dimension. It is frozen for intraoperative consultation.

6A frozen section block resubmitted

Quick Section Diagnosis

1. Left lower parathyroid: cellular parathyroid tissue with piece of thymic tissue.

Slide received _____; reported _____ (seen by Dr. _____)

2. Right lower parathyroid: positive for parathyroid tissue.

Slide received _____; reported _____

Source: NCI Genomic Data Commons file 38aff01b-3637-47d8-a0d5-5eeb6801ceee (TCGA-EM-A2CK.993E18F7-4FD8-4867-8921-55182FE4BFBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).